Somatic mutation profile of tumor specimen TCGA-AG-3592-01A (aliquot TCGA-AG-3592-01A-02D-1733-10) from TCGA case TCGA-AG-3592, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIA; Age at diagnosis: 68.8 years (25,141 days).
Specimen TCGA-AG-3592-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ea6abe6-949f-42d5-abcc-ca8417a4a116.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-3592-10A (Blood Derived Normal), aliquot TCGA-AG-3592-10A-01D-1733-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5abb7feb-3c1c-48b1-a625-e63eea07615f

The open-access MAF lists 285 somatic variants for this specimen: 216 protein-altering or splice-affecting, 66 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 190, Silent 66, Nonsense Mutation 14, Frame Shift Ins 6, Splice Site 3, 3'UTR 2, Intron 1, Frame Shift Del 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANO5 | c.1210C>T p.R404* | Nonsense Mutation (SNP) | VAF 3/14 reads (21%) | catalogued as rs566415362, CM1212694, COSV61082355; ClinVar: pathogenic; called by muse, mutect2
- OTC | c.533C>T p.T178M | Missense Mutation (SNP) | VAF 179/204 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs72556284, CM950878, COSV50000671; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 32/44 reads (73%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA13 | c.9005T>A p.L3002H | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71284052, COSV71284585; called by muse, mutect2, varscan2
- ABCB1 | c.3031A>G p.I1011V | Missense Mutation (SNP) | VAF 54/376 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV99714874; called by muse, mutect2, varscan2
- ACP4 | c.850A>G p.M284V | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.055); catalogued as COSV54516401; called by muse, mutect2, varscan2
- ADAMTS18 | c.1756C>T p.R586W | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs769577910, COSV51400683; called by muse, mutect2, varscan2
- ADAMTS5 | c.271G>A p.V91I | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV53176870; called by muse, mutect2, varscan2
- ADARB2 | c.1204C>T p.R402W | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs766263863, COSV67217567; called by muse, mutect2
- ADGRG4 | c.1143G>C p.K381N | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV54951593; called by muse, mutect2, varscan2
- ADH1B | c.291G>T p.Q97H | Missense Mutation (SNP) | VAF 82/261 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as COSV59295552; called by muse, mutect2, varscan2
- APBA2 | c.607G>A p.G203R | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs764880305, COSV68789491; called by muse, mutect2, varscan2
- APC | c.3989dup p.R1331* | Frame Shift Ins (INS) | VAF 38/104 reads (37%) | catalogued as COSV57404064; called by pindel, varscan2
- APLNR | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.023); catalogued as rs753846480, COSV57241710; called by muse, mutect2, varscan2
- ARHGAP1 | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs760960194, COSV100358100; ClinVar: likely benign; called by muse, mutect2, varscan2
- ASPN | c.943C>T p.Q315* | Nonsense Mutation (SNP) | VAF 35/384 reads (9%) | catalogued as COSV65015968; called by muse, mutect2
- ASTN2 | c.691C>T p.R231* | Nonsense Mutation (SNP) | VAF 14/50 reads (28%) | catalogued as rs767177206, COSV57759117; called by muse, mutect2, varscan2
- ATM | c.672G>C p.K224N | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as rs769731317, COSV53728366; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP2B3 | c.3581C>T p.T1194M | Missense Mutation (SNP) | VAF 59/72 reads (82%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.781); catalogued as rs782536019, COSV54842511; called by muse, mutect2, varscan2
- AURKC | c.230C>T p.S77L (on ENST00000302804 / NM_001015878.2; = p.S43L on NM_003160.3) | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as COSV57137280; called by muse, mutect2, varscan2
- BNC2 | c.3005C>T p.S1002L | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as rs752799809, COSV66161827; called by muse, mutect2, varscan2
- BRINP1 | c.749T>C p.I250T | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV56294527; called by muse, mutect2, varscan2
- BUD31 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs865774528, COSV52861652, COSV99463589; called by muse, mutect2, varscan2
- C11orf45 | c.121C>T p.Q41* | Nonsense Mutation (SNP) | VAF 32/68 reads (47%) | catalogued as COSV100171600; called by muse, mutect2, varscan2
- CACNB2 | c.1755C>G p.H585Q (on ENST00000324631 / NM_201596.3; = p.H530Q on NM_000724.4) | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as COSV56615198; called by muse, mutect2, varscan2
- CAPN5 | c.1562G>A p.G521D (on ENST00000456580; = p.G481D on NM_004055.5) | Missense Mutation (SNP) | VAF 64/143 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs782027905, COSV53686220; called by muse, mutect2, varscan2
- CARMIL3 | c.1753G>A p.G585R | Missense Mutation (SNP) | VAF 47/65 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1304537016, COSV57725376; called by muse, mutect2, varscan2
- CASZ1 | c.2191C>A p.L731M | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.02); catalogued as COSV59733119; called by muse, mutect2, varscan2
- CD1E | c.856C>T p.R286W | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); catalogued as rs368634701; called by muse, mutect2, varscan2
- CD22 | c.921C>A p.Y307* | Nonsense Mutation (SNP) | VAF 9/52 reads (17%) | catalogued as COSV50050258; called by muse, mutect2, varscan2
- CDH22 | c.1505C>T p.P502L | Missense Mutation (SNP) | VAF 23/233 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.023); catalogued as rs868625733, COSV64836806; called by muse, mutect2, varscan2
- CELSR2 | c.7622C>T p.A2541V | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.793); catalogued as rs751223026, COSV54768367; called by muse, mutect2, varscan2
- CNTN3 | c.1496C>T p.P499L | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV55165453; called by muse, mutect2, varscan2
- COL6A5 | c.7304G>T p.C2435F (on ENST00000312481; = p.C2431F on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55195710; called by muse, mutect2
- COL9A1 | c.172G>T p.D58Y | Missense Mutation (SNP) | VAF 62/138 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as COSV61829994; called by muse, mutect2, varscan2
- COPZ2 | c.289G>A p.G97S | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.788); catalogued as COSV99133938; called by muse, mutect2, varscan2
- CORO2B | c.142G>A p.V48I | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); catalogued as rs767629491, COSV55951202; called by muse, mutect2, varscan2
- CPXM2 | c.2038C>T p.R680C | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs749163201, COSV53858145, COSV53863962; called by muse, mutect2, varscan2
- CREBBP | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52114930; called by muse, mutect2, varscan2
- CRX | c.649G>A p.G217S | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs146869548; called by muse, mutect2, varscan2
- CTDP1 | c.1876G>A p.V626M | Missense Mutation (SNP) | VAF 36/48 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs761839272, COSV50001451; called by muse, mutect2, varscan2
- CTTNBP2NL | c.424A>T p.R142W | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54743523; called by muse, mutect2, varscan2
- DCT | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 85/188 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs751146188, COSV65467948; called by muse, mutect2, varscan2
- DDX59 | c.1780C>G p.Q594E | Missense Mutation (SNP) | VAF 105/456 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as COSV58750875; called by muse, mutect2, varscan2
- DENND4A | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1298457822, COSV71265355; called by muse, mutect2, varscan2
- DMXL1 | c.8800G>A p.V2934I | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs752290889, COSV60706638; called by muse, mutect2, varscan2
- DNAH10 | c.11876G>A p.R3959Q (on ENST00000409039; = p.R3898Q on NM_207437.3) | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.052); catalogued as rs1051360754, COSV101292217, COSV68989681; called by muse, mutect2, varscan2
- DNMT3B | c.306+1G>C p.X102_splice | Splice Site (SNP) | VAF 10/106 reads (9%) | catalogued as rs1386013606, COSV52415858; called by muse, mutect2, varscan2
- DPPA4 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 46/240 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs201448153, COSV59509600, COSV59509654; called by muse, mutect2, varscan2
- EBF2 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs1186478301, COSV68776629; called by muse, mutect2, varscan2
- EHMT2 | c.3607G>A p.G1203S | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs563892777, COSV57668085; called by muse, mutect2, varscan2
- EML5 | c.2072G>T p.R691L | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779121960, COSV61342946, COSV61345310; called by muse, mutect2, varscan2
- EPHA10 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.022); catalogued as rs781544726, COSV60402475; called by muse, mutect2, varscan2
- ETV5 | c.1379C>T p.P460L | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs1391685751, COSV60500340, COSV60507082; called by muse, mutect2, varscan2
- F8 | c.2717C>A p.S906* | Nonsense Mutation (SNP) | VAF 19/48 reads (40%) | catalogued as CM1314191, COSV100812161; called by muse, mutect2, varscan2
- FAM111A | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs202134817; called by muse, mutect2, varscan2
- FASLG | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 49/220 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.014); catalogued as rs1041898198, COSV60679889; called by muse, mutect2, varscan2
- FASN | c.3422G>T p.C1141F | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.854); catalogued as COSV100148487; called by muse, mutect2, varscan2
- FAT4 | c.9629C>A p.P3210Q | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58675513; called by muse, mutect2, varscan2
- FGA | c.1171G>A p.G391R | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); catalogued as rs1560825216, COSV57393972; called by muse, mutect2, varscan2
- FLG | c.5711A>G p.Q1904R | Missense Mutation (SNP) | VAF 114/474 reads (24%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.671); catalogued as COSV100912470; called by muse, varscan2
- FLG | c.5282G>A p.R1761H | Missense Mutation (SNP) | VAF 97/397 reads (24%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.976); catalogued as rs375545359, COSV64238304, COSV64253285; called by muse, mutect2, varscan2
- FLG | c.3229C>T p.H1077Y | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.881); catalogued as rs557910401, COSV64238309; called by muse, mutect2, varscan2
- FLT4 | c.2710G>A p.G904S | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1466649601, COSV56101552; called by muse, mutect2, varscan2
- FREM2 | c.6178G>C p.D2060H | Missense Mutation (SNP) | VAF 81/187 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54831306; called by muse, mutect2, varscan2
- FRRS1L | c.577G>T p.E193* | Nonsense Mutation (SNP) | VAF 68/152 reads (45%) | catalogued as COSV73746414; called by muse, mutect2, varscan2
- FRYL | c.7909G>C p.E2637Q | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.027); catalogued as COSV51942063, COSV51960485; called by muse, mutect2
- FYB2 | c.1309C>A p.Q437K | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.616); catalogued as rs371955958, COSV58583427; called by muse, mutect2, varscan2
- GANC | c.2483A>C p.Q828P | Missense Mutation (SNP) | VAF 80/246 reads (33%) | PolyPhen benign (0.212); catalogued as COSV58807856; called by muse, mutect2, varscan2
- GATA2 | c.1096G>A p.G366R | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758912342, COSV62003480; called by muse, mutect2, varscan2
- GATA3 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs752779081, COSV60515113; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GHR | c.1127A>G p.N376S | Missense Mutation (SNP) | VAF 93/165 reads (56%) | SIFT tolerated (0.37); PolyPhen benign (0.129); catalogued as COSV100052404; called by muse, mutect2, varscan2
- GLI3 | c.500C>T p.T167M | Missense Mutation (SNP) | VAF 25/194 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs752525209, COSV67886215; called by muse, mutect2, varscan2
- GLIS3 | c.2057C>T p.S686F | Missense Mutation (SNP) | VAF 34/214 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.467); catalogued as COSV100173765, COSV60925585; called by muse, mutect2, varscan2
- GLRA1 | c.488C>T p.T163I | Missense Mutation (SNP) | VAF 18/245 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.042); catalogued as rs773242874, COSV99199742; called by muse, mutect2
- GMPS | c.2030G>A p.R677Q | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55808360, COSV55810645; called by muse, mutect2, varscan2
- GPR158 | c.1549C>T p.R517* | Nonsense Mutation (SNP) | VAF 98/376 reads (26%) | catalogued as rs1397938078, COSV66280306; called by muse, mutect2, varscan2
- GPR182 | c.637A>T p.T213S | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV55625724; called by muse, mutect2, varscan2
- GREB1 | c.5149G>A p.V1717M | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs377649994; called by muse, mutect2, varscan2
- GRHL3 | c.1237C>T p.R413W (on ENST00000350501 / NM_198174.3; = p.R418W on NM_021180.3) | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1314361752, COSV99359812; called by muse, mutect2, varscan2
- GRIK5 | c.2188C>T p.R730W | Missense Mutation (SNP) | VAF 91/254 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53475988; called by muse, mutect2, varscan2
- GRM7 | c.235C>G p.L79V | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as COSV63134311; called by muse, mutect2, varscan2
- GTPBP8 | c.675A>C p.L225F | Missense Mutation (SNP) | VAF 92/372 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99868576; called by muse, mutect2, varscan2
- GUCY2F | c.549C>G p.F183L | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54299538; called by muse, mutect2, varscan2
- GYS2 | c.1264C>T p.R422* | Nonsense Mutation (SNP) | VAF 104/196 reads (53%) | catalogued as rs755733385, COSV53921287; called by muse, mutect2, varscan2
- HERC6 | c.1880T>G p.F627C | Missense Mutation (SNP) | VAF 92/547 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as COSV52028471; called by muse, mutect2, varscan2
- HOXB13 | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0.084); catalogued as COSV51704371; called by muse, mutect2, varscan2
- HRNR | c.5578C>T p.R1860* | Nonsense Mutation (SNP) | VAF 33/437 reads (8%) | catalogued as rs774806759, COSV64262306; called by muse, mutect2
- HYDIN | c.13639C>T p.R4547C | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101125275; called by muse, mutect2, varscan2
- HYDIN | c.5674C>T p.R1892C | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1198665807, COSV99992517; called by muse, mutect2, varscan2
- HYDIN | c.2541dup p.S848Ifs*6 | Frame Shift Ins (INS) | VAF 22/88 reads (25%) | catalogued as rs1188169133; called by mutect2, pindel, varscan2
- IDH3A | c.355G>T p.D119Y | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV100211086; called by muse, mutect2, varscan2
- IP6K3 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 34/221 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.141); catalogued as COSV53389440; called by muse, mutect2, varscan2
- KCNA5 | c.1060C>T p.R354W | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs746268474, COSV52903764; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNH2 | c.343G>A p.V115M | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as rs150988911, CM085488; ClinVar: not provided / uncertain significance; called by muse, mutect2, varscan2
- KCNH3 | c.2071C>T p.R691C | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as rs775702381, COSV57789943; called by muse, mutect2, varscan2
- KHDRBS2 | c.343_345del p.E115del | In Frame Del (DEL) | VAF 17/100 reads (17%) | catalogued as rs1441297110; called by pindel, varscan2
- KLHDC7A | c.2125C>T p.R709W | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs374396134; called by muse, mutect2, varscan2
- KRT28 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.577); catalogued as rs1011651056, COSV60683770; called by muse, mutect2, varscan2
- LAMA2 | c.7660T>A p.F2554I | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70341920; called by muse, mutect2, varscan2
- LHFPL6 | c.518C>T p.T173M | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.897); catalogued as rs755812608, COSV65444296; called by muse, mutect2, varscan2
- LILRB5 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 87/199 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.055); catalogued as rs761173913, COSV60255609; called by muse, mutect2, varscan2
- LIPT1 | c.150G>A p.W50* | Nonsense Mutation (SNP) | VAF 66/274 reads (24%) | catalogued as COSV100399576; called by muse, varscan2
- LRRC4C | c.1082C>A p.A361E | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.057); catalogued as rs764899167, COSV53420284; called by muse, mutect2, varscan2
- LRRIQ1 | c.1438A>C p.M480L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV67827270; called by muse, mutect2, varscan2
- MEGF8 | c.4516C>T p.R1506C (on ENST00000251268 / NM_001271938.2; = p.R1439C on NM_001410.3) | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs142361779; called by muse, mutect2, varscan2
- MGA | c.3451G>A p.E1151K | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV54950617; called by muse, mutect2, varscan2
- MGRN1 | c.1249T>C p.S417P | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as COSV52149209; called by muse, mutect2, varscan2
- MIA | c.107G>A p.C36Y | Missense Mutation (SNP) | VAF 81/209 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs375928719; called by muse, mutect2, varscan2
- MKI67 | c.5569dup p.I1857Nfs*52 | Frame Shift Ins (INS) | VAF 142/676 reads (21%) | catalogued as rs866533107; called by mutect2, varscan2
- MMRN1 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV99307963; called by muse, mutect2, varscan2
- MRC1 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 66/437 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs782266740, COSV58888782; called by muse, mutect2, varscan2
- MUC5B | c.14293C>G p.P4765A | Missense Mutation (SNP) | VAF 17/336 reads (5%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.005); catalogued as COSV71591674; called by muse, mutect2
- MYB | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 80/155 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1335964521, COSV57196482; called by muse, mutect2, varscan2
- MYH2 | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as rs772963819, COSV55430947; called by muse, mutect2, varscan2
- MYNN | c.1443T>G p.I481M | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.882); catalogued as COSV62991020; called by muse, mutect2, varscan2
- MYRIP | c.744G>C p.Q248H | Missense Mutation (SNP) | VAF 40/201 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV56864260; called by muse, mutect2, varscan2
- NAV3 | c.2951C>T p.S984L | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as rs1005877698, COSV57058762; called by muse, mutect2, varscan2
- NBEA | c.7045G>T p.A2349S | Missense Mutation (SNP) | VAF 83/187 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV59767326; called by muse, mutect2, varscan2
- NCAM2 | c.2174T>G p.F725C | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs916814696, COSV53061997; called by muse, mutect2, varscan2
- NINL | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs774911165, COSV53999716; called by muse, mutect2, varscan2
- NLRP2 | c.2612C>G p.T871R | Missense Mutation (SNP) | VAF 57/286 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99672794; called by muse, mutect2, varscan2
- NOTCH1 | c.2219A>T p.D740V | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0.014); catalogued as COSV99493047; called by muse, mutect2, varscan2
- NR1H4 | c.862-1G>C p.X288_splice (on ENST00000551379 / NM_001206993.2; = p.X274_splice on NM_005123.4) | Splice Site (SNP) | VAF 24/405 reads (6%) | catalogued as COSV99500144, COSV99501356; called by muse, mutect2
- OBSCN | c.16582G>A p.A5528T | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs773392960, COSV52751390; called by muse, mutect2, varscan2
- ODF3L1 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs147726214; called by muse, mutect2, varscan2
- OLFML2B | c.1535G>A p.R512Q | Missense Mutation (SNP) | VAF 141/283 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as rs141945594; called by muse, mutect2, varscan2
- OR13F1 | c.58T>A p.Y20N | Missense Mutation (SNP) | VAF 22/304 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100594894; called by muse, mutect2
- OR2A4 | c.103G>A p.V35I | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59575715; called by muse, mutect2, varscan2
- OR52I1 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 27/259 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs781255764, COSV56167917; called by muse, mutect2, varscan2
- OR8H1 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 82/193 reads (42%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs1173166538, COSV57293407; called by muse, varscan2
- OR8H1 | c.367G>A p.V123I | Missense Mutation (SNP) | VAF 28/235 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs1369006802, COSV57293417; called by muse, varscan2
- P2RY1 | c.797T>C p.L266P | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59309002; called by muse, mutect2, varscan2
- P3H1 | c.1243G>A p.V415I | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs147423732; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PADI2 | c.754G>A p.V252M | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs192937557, COSV100971118; called by muse, mutect2, varscan2
- PCDH17 | c.3214T>G p.L1072V | Missense Mutation (SNP) | VAF 27/268 reads (10%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.015); catalogued as COSV64971461, COSV64971783, COSV64972529; called by muse, mutect2, varscan2
- PCDHA5 | c.1927C>T p.R643C | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.901); catalogued as COSV65350338; called by muse, mutect2, varscan2
- PCDHA5 | c.2155G>A p.A719T | Missense Mutation (SNP) | VAF 24/260 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.734); catalogued as rs1554129666, COSV65350345; called by muse, mutect2, varscan2
- PCDHB7 | c.2239T>C p.Y747H | Missense Mutation (SNP) | VAF 10/213 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.609); catalogued as rs1359380173; called by muse, mutect2
- PDP1 | c.796C>T p.R266* | Nonsense Mutation (SNP) | VAF 95/252 reads (38%) | catalogued as COSV52600461; called by muse, mutect2, varscan2
- PEAK3 | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs754647937, COSV59701050; called by muse, mutect2, varscan2
- PEDS1 | c.586C>A p.P196T | Missense Mutation (SNP) | VAF 124/395 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59010758; called by muse, mutect2, varscan2
- PGA5 | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 303/878 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV56715024; called by muse, mutect2, varscan2
- PHF14 | c.941A>C p.Q314P | Missense Mutation (SNP) | VAF 54/439 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.84); catalogued as rs188488010, COSV68854594; called by muse, mutect2, varscan2
- PKHD1L1 | c.2455T>G p.S819A | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV65739334; called by muse, mutect2, varscan2
- PLEKHG2 | c.3631G>T p.A1211S | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.76); catalogued as COSV52679836, COSV52689306; called by muse, mutect2, varscan2
- PODN | c.221G>C p.R74T (on ENST00000395871; = p.R26T on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.201); catalogued as COSV57011675; called by muse, mutect2, varscan2
- POLRMT | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 34/180 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV73933168; called by muse, mutect2, varscan2
- PPFIBP1 | c.2605C>T p.H869Y (on ENST00000318304 / NM_177444.3; = p.H863Y on NM_003622.4) | Missense Mutation (SNP) | VAF 71/139 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57288922; called by muse, mutect2, varscan2
- PPIG | c.721C>A p.H241N | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.281); catalogued as rs1279282999, COSV53641821; called by muse, mutect2, varscan2
- PPIL3 | c.230A>T p.E77V (on ENST00000392283 / NM_130906.3; = p.E81V on NM_032472.4) | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV53768757; called by muse, mutect2, varscan2
- PPIL3 | c.229G>A p.E77K (on ENST00000392283 / NM_130906.3; = p.E81K on NM_032472.4) | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.223); catalogued as COSV53768777; called by muse, mutect2, varscan2
- PTK7 | c.789G>C p.E263D | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.029); catalogued as COSV57847194; called by muse, mutect2, varscan2
- PTPN14 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs750538905, COSV65282138, COSV65287363; called by muse, mutect2, varscan2
- PYROXD1 | c.1111C>A p.Q371K | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV53708462; called by muse, mutect2, varscan2
- PZP | c.2243A>T p.E748V | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as COSV54356142; called by muse, mutect2, varscan2
- RAB20 | c.677A>G p.K226R | Missense Mutation (SNP) | VAF 72/246 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs776553635, COSV57439948; called by muse, mutect2, varscan2
- RASGRP3 | c.740G>A p.G247D | Missense Mutation (SNP) | VAF 140/259 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67820942; called by muse, mutect2, varscan2
- RNF213 | c.6041A>G p.N2014S | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV60392457; called by muse, mutect2, varscan2
- RNF217 | c.1528G>C p.A510P (on ENST00000521654 / NM_001286398.2; = p.A218P on NM_152553.5) | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV51575001; called by muse, mutect2, varscan2
- RPL37 | c.113G>A p.G38D | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV57037737; called by muse, mutect2, varscan2
- RYR2 | c.12211G>A p.E4071K | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs779394700, COSV63670461, COSV63685976, COSV63686552; called by muse, mutect2, varscan2
- SEZ6L2 | c.584G>A p.R195H (on ENST00000308713 / NM_001114099.3; = p.R125H on NM_012410.4) | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.213); catalogued as rs199941854, COSV58097866; called by muse, mutect2, varscan2
- SHOX | c.190G>A p.G64S | Missense Mutation (SNP) | VAF 128/169 reads (76%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as CM074520, COSV61860082, COSV61860361; called by muse, mutect2, varscan2
- SLC1A1 | c.905C>T p.P302L | Missense Mutation (SNP) | VAF 185/698 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV52052930; called by muse, mutect2, varscan2
- SLC34A2 | c.1687G>A p.V563I | Missense Mutation (SNP) | VAF 79/187 reads (42%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs766256521, COSV65940930; called by muse, mutect2, varscan2
- SLC4A3 | c.470del p.H157Pfs*113 | Frame Shift Del (DEL) | VAF 16/34 reads (47%) | catalogued as rs759883814, COSV56092392; called by mutect2, varscan2
- SLITRK5 | c.89T>A p.V30E | Missense Mutation (SNP) | VAF 50/341 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.078); catalogued as COSV100281379; called by muse, mutect2, varscan2
- SNX19 | c.2891A>G p.D964G | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV99773758; called by muse, mutect2, varscan2
- SPTAN1 | c.1694G>A p.R565H | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as rs376897533; called by muse, mutect2, varscan2
- STARD7 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 91/321 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as rs181733184, COSV61525230; called by muse, mutect2, varscan2
- STEAP4 | c.565A>G p.I189V | Missense Mutation (SNP) | VAF 209/384 reads (54%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV57328437; called by muse, mutect2, varscan2
- STK24 | c.966G>T p.A322= | Splice Region (SNP) | VAF 11/223 reads (5%) | catalogued as COSV100925059; called by muse, mutect2
- STX1A | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as COSV56108790; called by muse, mutect2, varscan2
- SVEP1 | c.1078T>G p.C360G | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100239393; called by muse, mutect2, varscan2
- SYNE1 | c.15334G>T p.E5112* (on ENST00000367255 / NM_182961.4; = p.E5041* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 43/178 reads (24%) | catalogued as COSV54929750; called by muse, mutect2, varscan2
- SYNE2 | c.19244T>A p.I6415N | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100648650; called by muse, mutect2, varscan2
- TBC1D4 | c.1072C>G p.L358V | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV66488122; called by muse, mutect2, varscan2
- TENM3 | c.7309G>A p.E2437K | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.165); catalogued as rs1019400079, COSV69301857; called by muse, mutect2, varscan2
- TFAP2B | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.114); catalogued as COSV53831755; called by muse, mutect2, varscan2
- TFG | c.169A>C p.K57Q | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53747655; called by muse, mutect2, varscan2
- TIAM1 | c.4485G>T p.E1495D | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.8); PolyPhen benign (0.01); catalogued as COSV54541469; called by muse, mutect2
- TNRC6B | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.971); catalogued as COSV57290850; called by muse, mutect2, varscan2
- TRIM50 | c.1084C>T p.R362C | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as rs202235505, COSV53090713; called by muse, mutect2, varscan2
- TRIM68 | c.862G>C p.D288H | Missense Mutation (SNP) | VAF 41/196 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.289); catalogued as COSV56167926; called by muse, mutect2, varscan2
- TTC21B | c.2646A>T p.L882F | Missense Mutation (SNP) | VAF 85/421 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV54628638; called by muse, mutect2, varscan2
- TTN | c.46738C>T p.R15580C (on ENST00000591111; = p.R8156C on NM_003319.4) | Missense Mutation (SNP) | VAF 82/391 reads (21%) | PolyPhen probably damaging (0.998); catalogued as rs780490612, COSV59935152, COSV60097144; called by muse, mutect2, varscan2
- TTN | c.44257G>C p.D14753H (on ENST00000591111; = p.D7329H on NM_003319.4) | Missense Mutation (SNP) | VAF 100/388 reads (26%) | PolyPhen probably damaging (0.999); catalogued as COSV59935178; called by muse, mutect2, varscan2
- TTN | c.36505G>A p.V12169M (on ENST00000591111; = p.V4745M on NM_003319.4) | Missense Mutation (SNP) | VAF 23/111 reads (21%) | PolyPhen possibly damaging (0.654); catalogued as rs763668057, COSV100636092; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- TTN | c.22991G>A p.R7664Q (on ENST00000591111; = p.R6737Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/90 reads (52%) | PolyPhen benign (0.021); catalogued as rs772430122, COSV59909491; called by muse, mutect2, varscan2
- TUBGCP2 | c.220A>C p.N74H | Missense Mutation (SNP) | VAF 62/125 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV53303891; called by muse, mutect2, varscan2
- TYK2 | c.2044G>C p.E682Q | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.367); catalogued as COSV53385476; called by muse, varscan2
- UROC1 | c.893A>T p.Q298L | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.039); catalogued as COSV99332630; called by muse, mutect2
- VAX1 | c.373G>A p.V125M | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as COSV53327826; called by muse, mutect2, varscan2
- VPS50 | c.2464G>T p.E822* | Nonsense Mutation (SNP) | VAF 29/214 reads (14%) | catalogued as COSV59916860; called by muse, mutect2, varscan2
- VWA3A | c.2692G>A p.A898T | Missense Mutation (SNP) | VAF 172/289 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs371603505; called by muse, mutect2, varscan2
- VWA8 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 37/258 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as rs61752290; called by muse, mutect2, varscan2
- WDR19 | c.1009T>C p.S337P | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); catalogued as COSV99976075; called by muse, mutect2, varscan2
- WDR35 | c.755C>G p.T252S | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV55601067; called by muse, mutect2, varscan2
- ZBP1 | c.371G>T p.R124M | Missense Mutation (SNP) | VAF 58/582 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV59060788; called by muse, mutect2
- ZFPM2 | c.1625C>A p.P542H | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV65872869; called by muse, mutect2, varscan2
- ZNF143 | c.1309C>T p.R437W | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV55178886; called by muse, mutect2, varscan2
- ZNF165 | c.909G>T p.W303C | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.842); catalogued as COSV101056120, COSV66102166; called by muse, mutect2, varscan2
- ZNF17 | c.358C>G p.H120D | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV56920935; called by muse, mutect2, varscan2
- ZNF304 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV56583608; called by muse, mutect2, varscan2
- ZNF442 | c.311G>T p.S104I | Missense Mutation (SNP) | VAF 59/275 reads (21%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.949); catalogued as COSV54420788; called by muse, mutect2, varscan2
- ZNF512B | c.264+1G>C p.X88_splice | Splice Site (SNP) | VAF 27/287 reads (9%) | catalogued as COSV53867019; called by muse, mutect2
- ZNF570 | c.605dup p.N202Kfs*6 | Frame Shift Ins (INS) | VAF 15/52 reads (29%) | catalogued as rs758109083; called by mutect2, varscan2
- ZNF644 | c.947A>G p.N316S | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs1161013787, COSV61346438; called by muse, mutect2, varscan2
- ZSCAN26 | c.1204G>T p.A402S (on ENST00000623276 / NM_001111039.2; = p.A268S on NM_152736.5) | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.346); catalogued as COSV52551872; called by muse, mutect2
- APC | c.1438dup p.Q480Pfs*5 | Frame Shift Ins (INS) | VAF 18/82 reads (22%) | called by mutect2, pindel, varscan2
- ATP6V1B1 | c.418A>T p.M140L | Missense Mutation (SNP) | VAF 9/172 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ATP8B4 | c.872T>A p.L291H | Missense Mutation (SNP) | VAF 4/67 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CD300LB | c.587C>A p.T196N | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- ENAM | c.2138dup p.D713Efs*6 | Frame Shift Ins (INS) | VAF 7/47 reads (15%) | called by mutect2, pindel, varscan2
- GNRHR | c.976T>G p.F326V | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ADAM21 | c.1482C>A p.I494= | Silent (SNP) | VAF 12/118 reads (10%) | catalogued as COSV99961626; called by muse, varscan2
- ADGRE3 | c.1410C>T p.V470= | Silent (SNP) | VAF 31/176 reads (18%) | catalogued as rs201863044, COSV53728897; called by muse, mutect2, varscan2
- AGRN | c.2352G>A p.V784= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as COSV65068254; called by muse, mutect2, varscan2
- ASL | c.528C>T p.H176= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as rs150557376; called by muse, mutect2, varscan2
- CADPS | c.2148C>T p.C716= | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as rs368353277; called by muse, mutect2, varscan2
- CCK | c.99G>A p.L33= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as COSV58183535; called by muse, mutect2, varscan2
- CDH7 | c.441C>T p.N147= | Silent (SNP) | VAF 40/53 reads (75%) | catalogued as rs143932384, COSV100543517; called by muse, mutect2, varscan2
- CHMP4B | c.375C>A p.I125= | Silent (SNP) | VAF 23/185 reads (12%) | catalogued as COSV54135172, COSV54135368; called by muse, mutect2, varscan2
- CLTCL1 | c.2709C>T p.S903= | Silent (SNP) | VAF 30/121 reads (25%) | catalogued as rs781824901, COSV54224298, COSV54226574; called by muse, mutect2, varscan2
- CRTAM | c.1114A>C p.R372= | Silent (SNP) | VAF 56/254 reads (22%) | catalogued as COSV57066812; called by muse, mutect2, varscan2
- CYP4F8 | c.624C>T p.F208= | Silent (SNP) | VAF 21/491 reads (4%) | catalogued as rs1180849229, COSV57855317; called by muse, mutect2
- DNAJB12 | c.588C>T p.S196= (on ENST00000338820; = p.S162= on NM_017626.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV58759892; called by muse, mutect2, varscan2
- DNAJC5G | c.126G>A p.L42= | Silent (SNP) | VAF 23/106 reads (22%) | catalogued as rs937385182, COSV56079646; called by muse, mutect2, varscan2
- DOCK2 | c.3987T>C p.Y1329= | Silent (SNP) | VAF 19/117 reads (16%) | catalogued as COSV56947159; called by muse, mutect2, varscan2
- DPYSL5 | c.1050C>T p.G350= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as rs772609424, COSV56509721; called by muse, mutect2, varscan2
- DTX3 | c.855G>A p.A285= | Silent (SNP) | VAF 34/64 reads (53%) | catalogued as rs376657147; called by muse, mutect2, varscan2
- FBN2 | c.219C>T p.R73= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as rs1208524038, COSV52499031; called by muse, mutect2
- FMN2 | c.4620G>A p.S1540= | Silent (SNP) | VAF 17/156 reads (11%) | catalogued as rs369715134, COSV60450123; called by muse, mutect2
- GRIN2A | c.843C>T p.Y281= | Silent (SNP) | VAF 24/150 reads (16%) | catalogued as rs554338361, COSV58024603, COSV58050093; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- HYDIN | c.14544G>A p.A4848= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs373475539; called by muse, mutect2, varscan2
- INSC | c.1068G>T p.L356= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as rs895996512, COSV65409312; called by muse, mutect2, varscan2
- KATNAL1 | c.120C>T p.C40= | Silent (SNP) | VAF 20/464 reads (4%) | catalogued as COSV101017280; called by muse, mutect2
- LAMA4 | c.360T>C p.D120= | Silent (SNP) | VAF 19/127 reads (15%) | catalogued as rs782460149, COSV100039875; called by muse, mutect2, varscan2
- LRRIQ1 | c.3645C>T p.H1215= | Silent (SNP) | VAF 40/77 reads (52%) | catalogued as rs143339016; called by muse, mutect2, varscan2
- MAN2A1 | c.2553A>G p.L851= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as rs1237575779, COSV54847379; called by muse, mutect2, varscan2
- MAP7 | c.1593G>A p.S531= | Silent (SNP) | VAF 24/45 reads (53%) | catalogued as COSV63417981; called by muse, mutect2, varscan2
- MTA1 | c.1134C>T p.N378= | Silent (SNP) | VAF 77/100 reads (77%) | catalogued as rs148214371; called by muse, mutect2, varscan2
- MTCH2 | c.570C>A p.I190= | Silent (SNP) | VAF 14/120 reads (12%) | catalogued as COSV100207015, COSV100207184; called by muse, mutect2, varscan2
- MTTP | c.1668C>T p.D556= | Silent (SNP) | VAF 31/77 reads (40%) | catalogued as rs751421159, COSV99645749; ClinVar: likely benign; called by muse, mutect2, varscan2
- MUC16 | c.4305T>G p.T1435= | Silent (SNP) | VAF 73/315 reads (23%) | catalogued as COSV67443997; called by muse, mutect2, varscan2
- MUC6 | c.2220C>T p.N740= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as rs376692745; called by muse, mutect2, varscan2
- NEFM | c.54C>T p.T18= | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as COSV55331068; called by muse, mutect2, varscan2
- NLRP4 | c.486G>A p.T162= | Silent (SNP) | VAF 42/186 reads (23%) | catalogued as rs186765708, COSV56710236; called by muse, mutect2, varscan2
- NLRP5 | c.1932C>T p.D644= | Silent (SNP) | VAF 35/77 reads (45%) | catalogued as rs776601668, COSV101173547, COSV66762842; called by muse, mutect2, varscan2
- NR5A1 | c.732C>A p.I244= | Silent (SNP) | VAF 45/105 reads (43%) | catalogued as COSV65294701; called by muse, mutect2, varscan2
- OCA2 | c.2271C>T p.H757= | Silent (SNP) | VAF 17/90 reads (19%) | catalogued as rs148894313; called by muse, mutect2, varscan2
- OGDH | c.2172C>T p.G724= | Silent (SNP) | VAF 31/78 reads (40%) | catalogued as COSV56046774; called by muse, mutect2, varscan2
- PCDH15 | c.789A>T p.P263= | Silent (SNP) | VAF 22/115 reads (19%) | catalogued as COSV57274170; called by muse, mutect2, varscan2
- PCDHA9 | c.1533C>T p.H511= | Silent (SNP) | VAF 55/203 reads (27%) | catalogued as rs782471432, COSV65324227; called by muse, mutect2, varscan2
- PCDHGA12 | c.2226C>T p.G742= | Silent (SNP) | VAF 21/120 reads (18%) | catalogued as rs1210691847, COSV52750554, COSV52759759; called by muse, mutect2, varscan2
- PCDHGA4 | c.2206C>T p.L736= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV53914078; called by muse, mutect2, varscan2
- PCED1B | c.54G>T p.V18= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as COSV71394974; called by muse, mutect2, varscan2
- POFUT2 | c.1002C>T p.A334= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as rs1484978974, COSV57958191; called by muse, mutect2, varscan2
- PPFIA3 | c.2445C>T p.D815= | Silent (SNP) | VAF 41/101 reads (41%) | catalogued as COSV61950246; called by muse, mutect2, varscan2
- PRRC2C | c.7722T>C p.T2574= (on ENST00000367742; = p.T2572= on NM_015172.4) | Silent (SNP) | VAF 188/404 reads (47%) | catalogued as COSV58902400; called by muse, mutect2, varscan2
- PTPRM | c.4200C>T p.C1400= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs377577785; called by muse, mutect2, varscan2
- ROBO2 | c.2005C>A p.R669= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as rs375822408; called by muse, mutect2, varscan2
- RUNDC3A | c.165G>A p.S55= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as rs200736626, COSV56637252; called by muse, mutect2, varscan2
- RYR2 | c.27C>T p.D9= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as COSV63922611; called by muse, mutect2, varscan2
- SH2D5 | c.1176C>T p.Y392= (on ENST00000444387 / NM_001103161.2; = p.Y308= on NM_001103160.2) | Silent (SNP) | VAF 73/157 reads (46%) | catalogued as rs765080174, COSV56115843; called by muse, mutect2, varscan2
- SIGLEC12 | c.789G>A p.K263= (on ENST00000291707 / NM_053003.4; = p.K145= on NM_033329.2) | Silent (SNP) | VAF 26/152 reads (17%) | catalogued as rs747982839, COSV52460076; called by muse, mutect2, varscan2
- SLC2A10 | c.657G>T p.L219= | Silent (SNP) | VAF 18/104 reads (17%) | catalogued as COSV63713904; called by muse, mutect2, varscan2
- SPATA6 | c.771G>T p.V257= | Silent (SNP) | VAF 39/191 reads (20%) | catalogued as COSV100893467; called by muse, mutect2, varscan2
- SSUH2 | c.822G>C p.V274= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as COSV58029362; called by muse, mutect2, varscan2
- TACR3 | c.438G>A p.A146= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as COSV59199325; called by muse, mutect2, varscan2
- THBS2 | c.2598C>T p.D866= | Silent (SNP) | VAF 223/578 reads (39%) | catalogued as rs770837780, COSV100828141, COSV64681551; called by muse, mutect2, varscan2
- TLX1 | c.612G>A p.P204= | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as rs1178108091, COSV64622343; called by muse, mutect2, varscan2
- TRIP6 | c.543C>T p.C181= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs765798443, COSV51931986; called by mutect2, varscan2
- TSHZ2 | c.1050C>A p.A350= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as COSV100296949; called by muse, mutect2, varscan2
- XIRP1 | c.837C>T p.D279= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as rs965365008, COSV61137447; called by muse, mutect2, varscan2
- XPOT | c.2433C>T p.S811= | Silent (SNP) | VAF 38/128 reads (30%) | catalogued as rs749009245, COSV60344364; called by muse, mutect2, varscan2
- ZBED8 | c.813T>C p.C271= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as COSV68824427; called by muse, mutect2, varscan2
- ZFHX3 | c.6501C>T p.N2167= | Silent (SNP) | VAF 42/223 reads (19%) | catalogued as rs367687288; called by muse, mutect2, varscan2
- ZNF208 | c.1047C>T p.A349= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as COSV101237269; called by muse, mutect2
- ZNF407 | c.504C>T p.F168= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV55245772; called by muse, mutect2, varscan2
- ZRANB2 | c.231G>C p.V77= | Silent (SNP) | VAF 49/214 reads (23%) | catalogued as COSV54671146; called by muse, mutect2, varscan2
- C10orf71 | c.*134T>C | 3'UTR (SNP) | VAF 10/44 reads (23%) | catalogued as rs1409239784, COSV100110771; called by muse, mutect2, varscan2
- LHX6 | c.*1C>T | 3'UTR (SNP) | VAF 38/75 reads (51%) | catalogued as rs370814560; called by muse, mutect2, varscan2
- RAP1GAP | c.1429-910C>T | Intron (SNP) | VAF 8/42 reads (19%) | catalogued as rs375772076; called by muse, mutect2, varscan2
